Somatic mutation profile of tumor specimen TCGA-2G-AAFZ-01A (aliquot TCGA-2G-AAFZ-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAFZ, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 32.2 years (11,761 days).
Specimen TCGA-2G-AAFZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38269dc8-0b71-425a-8a14-d1c1f145af6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAFZ-10A (Blood Derived Normal), aliquot TCGA-2G-AAFZ-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d18f61d7-16de-4c1b-aa04-6808a3c9bc58

The open-access MAF lists 29 somatic variants for this specimen: 16 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 9, Intron 2, 3'UTR 1, Splice Site 1, Splice Region 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HIVEP1 | c.5329G>A p.V1777M | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs760693696, COSV65100827; called by muse, mutect2
- SIGLEC9 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as rs764072934, COSV51582602, COSV51583355; called by muse, mutect2, varscan2
- SLC30A9 | c.44G>C p.W15S | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as rs769918635, COSV52558273; called by muse, mutect2, varscan2
- TDRD6 | c.3844G>A p.G1282R | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs771080628; called by muse, mutect2, varscan2
- TMEM102 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.006); catalogued as rs556911261; called by muse, mutect2, varscan2
- ABTB1 | c.502G>A p.A168T (on ENST00000232744 / NM_172027.3; = p.A26T on NM_032548.3) | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); called by muse, mutect2
- C1S | c.1067-3T>G | Splice Region (SNP) | VAF 71/219 reads (32%) | called by muse, mutect2, varscan2
- EGR4 | c.1354A>T p.T452S (on ENST00000545030; = p.T349S on NM_001965.4) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHA3 | c.2332G>C p.A778P | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIN54 | c.1050G>T p.Q350H | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- LY6G5B | c.147C>G p.I49M | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- PPFIA2 | c.1529A>T p.E510V | Missense Mutation (SNP) | VAF 98/460 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- RBBP8NL | c.1783_1784dup p.T596Rfs*43 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | called by mutect2, varscan2
- RBM39 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- TRIP12 | c.4869+1G>A p.X1623_splice | Splice Site (SNP) | VAF 41/75 reads (55%) | called by muse, mutect2, varscan2
- TTC28 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- AP5Z1 | c.2073C>T p.P691= | Silent (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- EFHB | c.219A>T p.G73= | Silent (SNP) | VAF 28/373 reads (8%) | called by muse, mutect2
- HTR3B | c.39C>A p.I13= | Silent (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- IGFALS | c.1314G>A p.E438= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- MFSD2B | c.1179G>A p.L393= | Silent (SNP) | VAF 18/204 reads (9%) | called by muse, mutect2
- NFATC3 | c.33G>A p.E11= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- TENM3 | c.1395G>A p.T465= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as rs553919743; called by muse, mutect2
- TTC28 | c.1413T>C p.A471= | Silent (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- WNT5A | c.1119C>T p.I373= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as rs773053795, COSV52836801; called by muse, mutect2, varscan2
- ADPGK | c.840+125C>T | Intron (SNP) | VAF 9/19 reads (47%) | catalogued as rs958860808; called by muse, mutect2, varscan2
- CYS1 | c.*1G>A | 3'UTR (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- MIR299 | n.61C>G | RNA (SNP) | VAF 9/306 reads (3%) | called by muse, mutect2
- SPAG1 | c.1096+65T>G | Intron (SNP) | VAF 75/210 reads (36%) | called by muse, mutect2, varscan2
